Somatic mutation profile of tumor specimen TARGET-10-PARLTU-09A (aliquot TARGET-10-PARLTU-09A-01D) from TARGET case TARGET-10-PARLTU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.0 years (5,854 days).
Specimen TARGET-10-PARLTU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 555302c5-c03c-478f-b5f6-6fbf9390a6ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARLTU-14A (Bone Marrow Normal), aliquot TARGET-10-PARLTU-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b71da840-7fb9-4830-a911-07acdd66041e

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK1 | c.2729T>C p.L910P | Missense Mutation (SNP) | VAF 6/74 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61090359; called by muse, mutect2
- DCAF8L2 | c.667C>A p.R223S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.029); catalogued as rs1466678713; called by muse, mutect2
- JAK1 | c.1954T>A p.Y652N | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV61088550, COSV61093090, COSV61093632; called by muse, varscan2
- PAX5 | c.197G>A p.S66N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV99050245; called by muse, mutect2, varscan2
- ADGRE2 | c.1232G>T p.G411V | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.206); called by muse, mutect2
- ANKRD50 | c.3104G>T p.G1035V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CREB5 | c.1081C>A p.P361T (on ENST00000357727 / NM_182898.4; = p.P354T on NM_004904.3) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.066); called by muse, mutect2
- GREB1L | c.5662G>T p.V1888F | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPN9 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRQ | c.1376G>A p.W459* (on ENST00000616559; = p.W417* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 53/119 reads (45%) | called by muse, mutect2, varscan2
- XKR4 | c.1077C>A p.D359E | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.259); called by muse, mutect2
- ENPEP | c.1251A>C p.G417= | Silent (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- PPP4R3C | c.327C>A p.T109= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, varscan2
- RETREG1 | c.150G>T p.A50= | Silent (SNP) | VAF 39/84 reads (46%) | called by muse, mutect2, varscan2
- RP1L1 | c.1806G>A p.T602= | Silent (SNP) | VAF 70/162 reads (43%) | catalogued as rs374308509, COSV66756415; called by muse, mutect2
- SYTL1 | c.748-9del | Intron (DEL) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
